CPTAC case C3L-02955 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/42c00ea2-17e5-4f68-af9f-8c1f1bebed25

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Dead; Days to death: 378 days (1.0 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 76.3 years (27,855 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 378 days (1.0 years); Progression or recurrence: yes; Days to recurrence: 154 days; Days to last follow up: 350 days.
   Pathology details: Greatest tumor dimension: 3 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 329 days; Disease response: With Tumor.
- Days to follow up: 350 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 154 days.

Other clinical attributes
- Weight: 87.09 kg; Height: 162.56 cm; BMI: 32.95.

Exposures
- Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02955-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 218 mg; Time between excision and freezing: 24 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02955-21: Section location: Temporal Lobe; Percent tumor nuclei: 60; Percent necrosis: 10.
- Sample C3L-02955-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
